Somatic mutation profile of tumor specimen 0DHBD4 from CCDI case PBBTYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,871 days).
Specimen 0DHBD4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd458810-3cec-4d5e-9b01-0861fb078319.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHBCS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18511a4a-b6cf-46a6-87f9-be8efebedfbf

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, RNA 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 166/464 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PSKH2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); catalogued as COSV52609254; called by muse, mutect2, varscan2
- ZNF493 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765186904, COSV62750101; called by mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 32/894 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 150/424 reads (35%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, varscan2
- GMFB | c.358-51C>A | Intron (SNP) | VAF 13/104 reads (13%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 22/180 reads (12%) | called by muse, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 22/176 reads (13%) | catalogued as rs768118261; called by muse, varscan2
- PCDHGA9 | c.2424+95A>G | Intron (SNP) | VAF 23/300 reads (8%) | called by muse, mutect2
- SIMC1 | c.1677+98T>C | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as COSV104418257; called by muse, varscan2
